Gene-level copy-number profile of tumor specimen ALCH-B263-TTP1-A from ALCHEMIST case ALCH-B263, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.6 years (18,484 days).
Specimen ALCH-B263-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 95e40be6-c6cb-4ac7-8919-27a514b1daf7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B263-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/29b4684c-964c-4b4a-8fee-9c0689f336a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 126; copy number 1: 9,479; copy number 2: 47,438; copy number 3: 1,323; copy number 4: 10; copy number 5: 13.

Homozygous deletions (total copy number 0; autosomes only): 126 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,487,246–3,611,508, 3 genes: AL512413.1, MEGF6, MIR551A.
- chr1:3,652,516–3,736,201, 3 genes (within-gene range 0–2): TP73, TP73-AS3, TP73-AS2.
- chr1:3,736,943–3,737,103, 1 gene (within-gene range 0–2): AL136528.1.
- chr2:238,152,889–238,155,994, 1 gene (within-gene range 0–2): KLHL30-AS1.
- chr3:52,433,035–52,454,041, 2 genes: SEMA3G, TNNC1.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr4:2,247,432–2,262,109, 2 genes: MXD4, MIR4800.
- chr5:466,124–473,098, 1 gene (within-gene range 0–2): PP7080.
- chr5:473,236–535,882, 3 genes (within-gene range 0–1): SLC9A3-AS1, AC106772.2, MIR4456.
- chr5:1,005,039–1,006,623, 1 gene: AC116351.2.
- chr9:19,507,452–23,438,700, 77 genes (broad region; genes not listed).
- chr10:133,246,478–133,276,868, 4 genes: MIR202HG, MIR202, AL592071.1, ADAM8.
- chr12:131,924,736–131,945,896, 3 genes: AC131009.1, PUS1, AC131009.3.
- chr16:1,064,093–1,078,731, 2 genes: SSTR5-AS1, AC009041.2.
- chr17:1,022,476–1,022,559, 1 gene (within-gene range 0–1): MIR3183.
- chr17:17,810,399–17,837,011, 3 genes (within-gene range 0–1): SREBF1, MIR6777, MIR33B.
- chr17:61,393,456–61,413,280, 3 genes (within-gene range 0–2): TBX2-AS1, TBX2, LINC02875.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr19:5,782,960–5,791,225, 3 genes: PRR22, AC011499.1, DUS3L.
- chr19:18,434,388–18,438,167, 1 gene (within-gene range 0–2): ISYNA1.
- chr20:64,073,181–64,101,162, 5 genes: RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3.
- chr20:64,105,820–64,107,171, 1 gene: NPBWR2.
- chr21:44,978,832–44,979,274, 1 gene: AP001505.1.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:20,701,114–20,704,606, 1 gene: TMEM191A.
- chr22:45,875,932–45,879,247, 1 gene (within-gene range 0–2): BX324167.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 5 (within-gene range 2–5): TTC34, AC242022.2, AC242022.1.
- chr8:7,200,756–7,290,402, 8 genes, copy number 5: AF228730.1, AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P.
- chr16:1,771,890–1,773,150, 1 gene, copy number 5: MRPS34.
- chr21:43,446,601–43,453,902, 1 gene, copy number 5: LINC00319.

Autosomal genes at a single copy (total copy number 1): 7,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
